TCGA case TCGA-AP-A5FX — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a633d316-59a4-45ae-8bf8-135cfbd27656

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 1,099 days (3.0 years).

Diagnoses (2)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 68.6 years (25,063 days); Year of diagnosis: 2010; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IIIC1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 1,099 days (3.0 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 96.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 4; Lymph nodes tested: 4.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 84 days; Days to treatment end: 190 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 273 days; Days to treatment end: 305 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Recurrence of diagnosis 1 (Adenocarcinoma with mixed subtypes), site: Intra-abdominal lymph nodes. Age at diagnosis: 69.7 years (25,470 days); Days to diagnosis: 407 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 407 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 407 days (1.1 years).
- Days to follow up: 1,026 days (2.8 years); Disease response: With Tumor.
- Days to follow up: 1,099 days (3.0 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 168 cm; BMI: 28.3.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 4+; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AP-A5FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 300 mg.
  Slide TCGA-AP-A5FX-01A-01-TSA: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AP-A5FX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AP-A5FX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Mixed serous and endometrioid; Surgical approach at diagnosis: open; History colorectal cancer: No; Diabetes diagnosis indicator: Yes; History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,099 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,099 days; disease-free interval: event (new tumor event after initially disease-free), 407 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 407 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AP-A5FX-01A-11D-A27O-01): tumor purity 0.68, ploidy 3.41, whole-genome doublings 1.
